Somatic mutation profile of tumor specimen TARGET-10-PATFJD-09A (aliquot TARGET-10-PATFJD-09A-01D) from TARGET case TARGET-10-PATFJD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (920 days).
Specimen TARGET-10-PATFJD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa3814ee-1896-433a-a20c-89ada74d5ec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATFJD-14A (Bone Marrow Normal), aliquot TARGET-10-PATFJD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d0db91d-c5ea-471e-9d6b-a4a902f42407

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLGAP3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1221988636, COSV52395034; called by muse, mutect2, varscan2
- NOTCH1 | c.4583G>A p.C1528Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53060149, COSV53062582; called by muse, mutect2, varscan2
- SOX6 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as rs774770291, COSV57039221; called by muse, mutect2, varscan2
- SDC1 | c.*478G>A | 3'UTR (SNP) | VAF 19/44 reads (43%) | catalogued as rs375808587; called by muse, mutect2, varscan2
